Somatic mutation profile of tumor specimen TCGA-AA-3667-01A (aliquot TCGA-AA-3667-01A-01W-0900-09) from TCGA case TCGA-AA-3667, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 36.4 years (13,302 days).
Specimen TCGA-AA-3667-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf84889b-5eaf-4648-bb90-9b01a83f1a81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3667-10A (Blood Derived Normal), aliquot TCGA-AA-3667-10A-01W-0900-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ec9420c-8d3e-4410-a0c0-7c8cf9bac89d

The open-access MAF lists 73 somatic variants for this specimen: 59 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 13, Nonsense Mutation 4, Frame Shift Del 4, Frame Shift Ins 2, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1690C>T p.R564* | Nonsense Mutation (SNP) | VAF 76/168 reads (45%) | hotspot (GDC flag); catalogued as rs137854574, CM920035, COSV57321509; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 45/67 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A4GALT | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV50744396; called by muse, mutect2, varscan2
- AADAC | c.758del p.Y253Ffs*40 | Frame Shift Del (DEL) | VAF 167/348 reads (48%) | catalogued as COSV51759275; called by mutect2, pindel, varscan2
- ABCA13 | c.12096C>A p.H4032Q | Missense Mutation (SNP) | VAF 123/512 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV71287746; called by muse, mutect2, varscan2
- ACAD11 | c.299C>A p.P100H | Missense Mutation (SNP) | VAF 102/427 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53896160; called by muse, mutect2, varscan2
- APC | c.4199del p.S1400* | Frame Shift Del (DEL) | VAF 88/242 reads (36%) | catalogued as CM995167, COSV57324455, COSV57326621, COSV57333132; called by mutect2, pindel, varscan2
- APOB | c.6443dup p.Y2149Vfs*2 | Frame Shift Ins (INS) | VAF 43/142 reads (30%) | catalogued as COSV51933010; called by mutect2, pindel, varscan2
- ATP7B | c.1544G>A p.G515D | Missense Mutation (SNP) | VAF 18/358 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM136088, HM050020, COSV54441402; called by muse, mutect2
- CADM1 | c.1258G>A p.A420T | Missense Mutation (SNP) | VAF 142/300 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59010320; called by muse, mutect2, varscan2
- CCDC40 | c.1655C>T p.A552V | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.06); catalogued as rs1342938765, COSV66474728; called by muse, mutect2, varscan2
- CDK14 | c.124A>T p.I42L (on ENST00000380050 / NM_001287135.2; = p.I24L on NM_012395.3) | Missense Mutation (SNP) | VAF 147/455 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as COSV56034733; called by muse, mutect2, varscan2
- CMSS1 | c.691A>C p.K231Q | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV70436933, COSV70437677; called by muse, mutect2, varscan2
- CPXM1 | c.688C>A p.P230T | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.551); catalogued as COSV66045364; called by mutect2, varscan2
- CRTC1 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as rs540923120, COSV58718746; called by muse, mutect2
- CTCF | c.1507G>T p.A503S | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.166); catalogued as COSV50468532, COSV50506305; called by muse, mutect2, varscan2
- DCDC1 | c.856A>G p.M286V | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as COSV100662489; called by muse, mutect2
- EIF4A2 | c.1156C>A p.R386S | Missense Mutation (SNP) | VAF 124/392 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV56216956, COSV56217635, COSV99960966; called by muse, mutect2, varscan2
- EXOSC10 | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 27/86 reads (31%) | catalogued as COSV58665369; called by muse, mutect2, varscan2
- FBXO11 | c.1847C>G p.T616S (on ENST00000403359 / NM_001190274.2; = p.T532S on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/192 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.635); catalogued as COSV57019579; called by muse, mutect2, varscan2
- FMN2 | c.3562C>T p.P1188S | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated, low confidence (0.36); PolyPhen probably damaging (0.979); catalogued as COSV100141994; called by muse, mutect2, varscan2
- FMO1 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.099); catalogued as rs765073901, COSV61445185; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.917A>C p.D306A | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.782); catalogued as COSV58554099; called by muse, mutect2, varscan2
- GABRA5 | c.1316C>G p.T439S | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.05); catalogued as COSV59479613; called by muse, mutect2, varscan2
- GPD1L | c.87G>C p.K29N | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.261); catalogued as COSV56990018; called by muse, mutect2, varscan2
- GPR61 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs752917891, COSV68177668; called by muse, mutect2, varscan2
- HCN1 | c.1522G>A p.V508M | Missense Mutation (SNP) | VAF 73/183 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.192); catalogued as rs180790607, COSV57495369, COSV57501466; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1112A>C p.E371A | Missense Mutation (SNP) | VAF 64/161 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV57132230; called by muse, mutect2, varscan2
- JADE1 | c.1560C>G p.C520W | Missense Mutation (SNP) | VAF 69/219 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.289); catalogued as COSV56905950; called by muse, mutect2, varscan2
- KCTD21 | c.631G>C p.V211L | Missense Mutation (SNP) | VAF 137/339 reads (40%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV60741110, COSV60741428; called by muse, mutect2, varscan2
- KHSRP | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1264693215, COSV67919698; called by muse, mutect2, varscan2
- LCOR | c.3157G>A p.D1053N | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV53715882; called by muse, mutect2, varscan2
- LMX1A | c.862A>G p.N288D | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.155); catalogued as COSV54221122; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1973G>A p.G658E | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53797797; called by muse, mutect2, varscan2
- MUL1 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as rs139030069; called by muse, mutect2, varscan2
- N4BP1 | c.1169G>A p.R390K | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52210802; called by muse, mutect2, varscan2
- NUP205 | c.955C>G p.L319V | Missense Mutation (SNP) | VAF 66/247 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV53659143; called by muse, mutect2, varscan2
- OR4F15 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.462); catalogued as rs1228466075, COSV59969062, COSV99046067; called by muse, mutect2, varscan2
- PCDHGA5 | c.692C>T p.T231M | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.16); catalogued as rs1336541322, COSV53933747; called by muse, mutect2, varscan2
- PIK3CD | c.1339+2T>G p.X447_splice | Splice Site (SNP) | VAF 31/48 reads (65%) | catalogued as COSV100739900; called by muse, mutect2, varscan2
- PLS3 | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs370999829, COSV56779565; called by muse, mutect2
- PWWP3B | c.1150C>T p.H384Y | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.341); catalogued as COSV61799710; called by muse, mutect2, varscan2
- SETBP1 | c.1966G>C p.G656R | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); catalogued as COSV56321901; called by muse, mutect2, varscan2
- SETDB1 | c.2207G>A p.R736Q | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.886); catalogued as rs200603147; called by muse, mutect2, varscan2
- SNX33 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 92/167 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs998705036, COSV57913278, COSV57913597; called by muse, mutect2, varscan2
- SRSF8 | c.813dup p.K272Qfs*4 | Frame Shift Ins (INS) | VAF 6/60 reads (10%) | catalogued as rs781928250; called by pindel, varscan2
- SYNE2 | c.7277G>A p.S2426N | Missense Mutation (SNP) | VAF 53/80 reads (66%) | SIFT tolerated (0.76); PolyPhen benign (0.03); catalogued as rs1280896359, COSV59950918; called by muse, mutect2, varscan2
- TMBIM4 | c.317T>C p.L106P | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1484934433, COSV53968907; called by muse, mutect2, varscan2
- TRAV2 | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 117/153 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.144); catalogued as rs36082491; called by muse, mutect2, varscan2
- TTN | c.6239T>A p.I2080N (on ENST00000591111; = p.I2034N on NM_003319.4) | Missense Mutation (SNP) | VAF 77/194 reads (40%) | PolyPhen probably damaging (0.998); catalogued as COSV60059241; called by muse, varscan2
- VPS13B | c.487G>T p.V163F | Missense Mutation (SNP) | VAF 170/318 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV100660860, COSV62019427; called by muse, mutect2, varscan2
- WNK3 | c.2110C>G p.Q704E | Missense Mutation (SNP) | VAF 86/223 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.024); catalogued as rs1557155418, COSV63614015; called by muse, mutect2, varscan2
- ZCCHC12 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 133/354 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV59571635; called by muse, mutect2, varscan2
- ZFYVE16 | c.2506C>T p.Q836* | Nonsense Mutation (SNP) | VAF 85/212 reads (40%) | catalogued as rs541127111, COSV62015740; called by muse, mutect2, varscan2
- ZHX3 | c.1192A>G p.S398G | Missense Mutation (SNP) | VAF 39/281 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV58383489; called by muse, mutect2, varscan2
- ZNF334 | c.1913G>A p.R638H | Missense Mutation (SNP) | VAF 201/456 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs143648111; called by mutect2, varscan2
- ZNF493 | c.718A>T p.K240* | Nonsense Mutation (SNP) | VAF 87/255 reads (34%) | catalogued as COSV62750060; called by muse, mutect2, varscan2
- DOCK10 | c.1097_1098del p.I366Rfs*14 | Frame Shift Del (DEL) | VAF 24/60 reads (40%) | called by pindel, varscan2
- DRAM2 | c.84del p.T29Lfs*3 | Frame Shift Del (DEL) | VAF 69/245 reads (28%) | called by mutect2, pindel, varscan2
- CDH23 | c.8490G>A p.Q2830= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV56463412; called by muse, mutect2, varscan2
- CEP120 | c.84T>G p.L28= | Silent (SNP) | VAF 31/109 reads (28%) | catalogued as COSV60265536; called by muse, mutect2, varscan2
- DDX56 | c.73C>T p.L25= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as COSV99215467; called by muse, mutect2
- EBNA1BP2 | c.15G>A p.P5= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV52540084; called by muse, mutect2, varscan2
- ENPP6 | c.717G>A p.S239= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as rs144414378; called by muse, mutect2, varscan2
- GPR142 | c.567G>A p.R189= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV59519345; called by muse, mutect2, varscan2
- LAMP2 | c.1176G>A p.V392= | Silent (SNP) | VAF 152/399 reads (38%) | catalogued as rs758020252, COSV99568079; called by muse, mutect2, varscan2
- LRRTM3 | c.1428C>T p.T476= | Silent (SNP) | VAF 9/173 reads (5%) | catalogued as COSV100791410; called by muse, mutect2
- PCDHB9 | c.2157G>A p.A719= | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as rs1309114444, COSV53378735; called by muse, mutect2, varscan2
- PPP1R21 | c.1329A>G p.K443= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as COSV54284626; called by muse, mutect2, varscan2
- PSG4 | c.1170G>A p.G390= | Silent (SNP) | VAF 38/479 reads (8%) | catalogued as COSV99735972; called by muse, mutect2
- RAI14 | c.1938C>T p.S646= | Silent (SNP) | VAF 91/193 reads (47%) | catalogued as rs761812075, COSV54291947; called by muse, mutect2, varscan2
- ZFX | c.1527G>A p.V509= | Silent (SNP) | VAF 197/445 reads (44%) | catalogued as COSV58447576; called by muse, mutect2, varscan2
- DST | c.4297-1745A>G | Intron (SNP) | VAF 75/156 reads (48%) | catalogued as COSV55014268; called by muse, mutect2, varscan2
